Gene-level copy-number profile of tumor specimen TCGA-VR-AA4G-01A from TCGA case TCGA-VR-AA4G, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 51.8 years (18,909 days).
Specimen TCGA-VR-AA4G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.20139afe-ad04-4571-b779-0c4a51e74ada.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VR-AA4G-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/b912eed7-a881-4e29-84e0-7b0df016c34b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 11,527; copy number 2: 41,885; copy number 3: 4,206; copy number 4: 1,536; copy number 5: 534; copy number 6: 25; copy number 7: 14; copy number 9: 10; copy number 16: 52; copy number 22: 7.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:11,035,206–11,067,089, 2 genes: MIR598, AF131215.3.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,929,457–22,128,103, 8 genes (within-gene range 0–2): ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr10:34,201,979–34,488,878, 2 genes: Y_RNA, ELOBP4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 642 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:44,173,903–44,726,588, 7 genes, copy number 22 (within-gene range 1–22): KCTD8, AC093852.1, YIPF7, GUF1, GNPDA2, AC096586.2, AC096586.1.
- chr4:52,252,820–53,460,862, 20 genes, copy number 6 (within-gene range 2–6): AC097522.2, AC097522.1, RNU6-1252P, USP46, USP46-DT, AC104066.3, DANCR, LINC01618, MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1, Y_RNA, RASL11B, SCFD2, AC023154.1, RNU6-310P, FIP1L1.
- chr4:53,459,301–53,737,156, 5 genes, copy number 6: LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1.
- chr4:107,435,118–108,258,037, 10 genes, copy number 5: RNU6-551P, PAPSS1, SGMS2, CYP2U1-AS1, RNU6-733P, CYP2U1, AC096564.1, HADH, LEF1, LEF1-AS1.
- chr4:110,365,733–110,565,285, 1 gene, copy number 5 (within-gene range 3–5): ENPEP.
- chr4:110,415,898–115,113,876, 67 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr4:134,759,399–137,655,174, 28 genes, copy number 5–7: AC093722.1, AC104619.2, AC104619.4, AC104619.1, AC104619.3, AC107463.1, LINC02485, U6, KRT18P54, TARS2P1, AC105362.1, LINC00613, RNU1-89P, AC104136.1, AC073429.2, AC018680.1, AC073429.1, TERF1P3, AC093875.1, LINC02511, LINC02510, SERF1AP1, STMN1P2, RPS23P2, PCDH18, LINC02172, AC116563.2, AC116563.1.
- chr4:145,098,288–149,278,123, 65 genes, copy number 5 (broad region; genes not listed).
- chr4:149,377,257–149,380,107, 1 gene, copy number 5: AC108168.1.
- chr7:91,311,368–105,600,875, 376 genes, copy number 5 (broad region; genes not listed).
- chr11:68,754,620–71,252,577, 62 genes, copy number 9–16 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,106. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
